Somatic mutation profile of tumor specimen TCGA-AB-2869-03A (aliquot TCGA-AB-2869-03A-01W-0761-09) from TCGA case TCGA-AB-2869, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,679 days).
Specimen TCGA-AB-2869-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21075100-1b8d-4921-ac2d-76c0b6566f56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2869-11A (Solid Tissue Normal), aliquot TCGA-AB-2869-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f7f93d4-8102-47f6-9621-2ef35627ea34

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.2400G>T p.V800= | Splice Region (SNP) | VAF 8/15 reads (53%) | catalogued as rs755332087, COSV99819506; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 17/38 reads (45%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- VN1R4 | c.350del p.A117Efs*25 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs200548838, COSV60804555; called by mutect2, pindel, varscan2
